Somatic mutation profile of tumor specimen MMRF_2755_1_BM_CD138pos (aliquot MMRF_2755_1_BM_CD138pos_T1_KHS5U_L15089) from MMRF case MMRF_2755, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2755_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8b89d1b-7c33-4cb8-ac68-92d0871162d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2755_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2755_1_PB_WBC_C2_KHS5U_L15090; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/716421ef-31ad-4bc2-ad7e-5f7fb4c2f76c

The open-access MAF lists 148 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 39, Silent 18, Intron 16, Nonsense Mutation 5, 5'UTR 4, Frame Shift Del 3, Splice Site 3, 3'Flank 2, 5'Flank 2, Frame Shift Ins 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV51055694; called by muse, mutect2, varscan2
- BAZ1A | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1416634265; called by muse, mutect2, varscan2
- CCDC89 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs372046627; called by muse, mutect2
- CSE1L | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV53705742; called by muse, varscan2
- DCDC1 | c.2422T>G p.L808V | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.038); catalogued as COSV60851284; called by muse, mutect2, varscan2
- EPHB6 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs749587279; called by muse, mutect2, varscan2
- FAM13C | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as rs768921251; called by muse, mutect2, varscan2
- GRIK4 | c.2014G>C p.G672R | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773850072, COSV101483682; called by muse, mutect2, varscan2
- GRM5 | c.2455G>T p.V819L | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.992); catalogued as rs1239206665; called by muse, mutect2, varscan2
- IGHV2-70 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561745237; called by muse, varscan2
- IGHV2-70 | c.247T>A p.S83T | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs544603085; called by muse, varscan2
- KCTD15 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs769587521; called by muse, mutect2, varscan2
- LAMB2 | c.4684C>T p.R1562* | Nonsense Mutation (SNP) | VAF 28/171 reads (16%) | catalogued as rs774352333, CM042734, COSV59737532; called by muse, mutect2, varscan2
- MGA | c.7039G>T p.E2347* (on ENST00000219905 / NM_001164273.1; = p.E2138* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | catalogued as COSV54959416; called by muse, mutect2, varscan2
- MUC22 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT deleterious, low confidence (0.04); catalogued as rs982204309; called by muse, mutect2, varscan2
- PBXIP1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1321891145; called by muse, mutect2, varscan2
- PNPT1 | c.2013+1G>A p.X671_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as rs1315448682; called by muse, mutect2, varscan2
- PPEF2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs201749049, COSV54422501; called by muse, mutect2, varscan2
- RHOT2 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs764329068; called by muse, mutect2, varscan2
- SOCS1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs765434194, COSV59658627; called by muse, mutect2, varscan2
- TBX21 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51596571; called by muse, mutect2, varscan2
- TDRD9 | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV59149002; called by muse, mutect2, varscan2
- UNC119 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761823478, COSV56378839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF568 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.111); catalogued as rs372458318, COSV71278511; called by muse, mutect2, varscan2
- ADAD1 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- AGT | c.1138A>T p.T380S | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- AL021546.1 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 124/283 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCSER1 | c.1538A>T p.E513V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CD163 | c.2672A>G p.D891G | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- CD4 | c.1034A>T p.E345V | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CHD3 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CSE1L | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- DIP2A | c.1540-2A>C p.X514_splice | Splice Site (SNP) | VAF 71/255 reads (28%) | called by muse, mutect2, varscan2
- DMXL1 | c.3088dup p.I1030Nfs*2 | Frame Shift Ins (INS) | VAF 64/186 reads (34%) | called by mutect2, varscan2
- DSP | c.8489G>A p.R2830H | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EVC | c.1524G>C p.E508D | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GUCA2B | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGF2BP1 | c.1358T>C p.M453T | Missense Mutation (SNP) | VAF 16/425 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- IGHV1-69 | c.248_249delinsG p.F83Cfs*20 | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | called by pindel, varscan2*
- KIAA1109 | c.4466A>G p.E1489G | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPIN1 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 64/132 reads (48%) | called by muse, varscan2
- LPXN | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 165/377 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MGAT4D | c.926T>A p.L309* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- NAT10 | c.3058A>C p.K1020Q | Missense Mutation (SNP) | VAF 231/490 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, varscan2
- NCKAP5 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NECTIN1 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PKDREJ | c.5658dup p.P1887Sfs*7 | Frame Shift Ins (INS) | VAF 38/208 reads (18%) | called by mutect2, varscan2
- PLCB1 | c.1840T>C p.F614L | Missense Mutation (SNP) | VAF 241/364 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- RNF31 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SAMD4A | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SCAF11 | c.3446C>G p.A1149G | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELP | c.1891+2T>G p.X631_splice | Splice Site (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- SMAD2 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TCERG1 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TECPR1 | c.1673del p.G558Afs*53 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- TENT5C | c.384_385del p.K128Nfs*22 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- TMEM270 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- TTC29 | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TUBB4A | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP47 | c.2759C>T p.S920L (on ENST00000399455 / NM_001372095.1; = p.S832L on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- ZFHX3 | c.7790C>T p.P2597L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF182 | c.1284A>C p.K428N | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF583 | c.48_49insTAAGAGG p.Q17* | Nonsense Mutation (INS) | VAF 18/80 reads (23%) | called by mutect2, varscan2
- ZNF740 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ADGRE2 | c.276C>T p.Y92= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as rs376023757; called by muse, mutect2, varscan2
- AQR | c.1240C>A p.R414= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs756553023; called by muse, mutect2, varscan2
- BCL3 | c.114C>T p.R38= | Silent (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- CFAP43 | c.3993C>T p.F1331= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs144641240; called by muse, mutect2, varscan2
- CHRNB2 | c.1116C>T p.G372= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as rs1402931071, COSV63809021; ClinVar: likely benign; called by muse, mutect2, varscan2
- DTX4 | c.735C>A p.T245= | Silent (SNP) | VAF 33/264 reads (13%) | called by muse, mutect2, varscan2
- H4C2 | c.297C>T p.Y99= | Silent (SNP) | VAF 139/217 reads (64%) | catalogued as rs752778199; called by muse, mutect2, varscan2
- IGHJ3 | c.36C>G p.V12= | Silent (SNP) | VAF 28/33 reads (85%) | called by muse, varscan2
- IRX1 | c.708C>T p.H236= | Silent (SNP) | VAF 274/425 reads (64%) | catalogued as COSV57359874; called by muse, mutect2, varscan2
- KLF2 | c.825C>T p.S275= | Silent (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- KRTAP1-3 | c.396C>G p.T132= | Silent (SNP) | VAF 47/65 reads (72%) | catalogued as rs1490512877; called by muse, mutect2, varscan2
- MCOLN1 | c.948C>T p.C316= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs759397627; ClinVar: likely benign; called by muse, mutect2, varscan2
- MORC4 | c.1041G>A p.V347= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- MUC3A | c.9921C>A p.T3307= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs770524144; called by muse, mutect2
- NECTIN4 | c.219C>T p.G73= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- NEU4 | c.411C>A p.G137= (on ENST00000391969 / NM_001167602.3; = p.G149= on NM_080741.4) | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- PRDM9 | c.1170T>C p.C390= | Silent (SNP) | VAF 109/319 reads (34%) | called by muse, mutect2, varscan2
- SH2D2A | c.783A>T p.T261= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- BCAT1 | c.*3625G>C | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- BCL7A | chr12:122019747 A>T | 5'Flank (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- BMP6 | c.*1195_*1205del | 3'UTR (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- BMPR1B | chr4:95154862 T>G | 3'Flank (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- C19orf71 | c.83+72G>A | Intron (SNP) | VAF 48/78 reads (62%) | called by muse, mutect2, varscan2
- C1orf158 | c.*541C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- C1orf21 | c.*3704dup | 3'UTR (INS) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- CCDC183 | c.270+59dup | Intron (INS) | VAF 54/108 reads (50%) | catalogued as rs751769886; called by mutect2, varscan2
- CCDC88B | c.-38T>G | 5'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- CCND1 | c.*985_*987del | 3'UTR (DEL) | VAF 35/108 reads (32%) | catalogued as rs1346262089; called by pindel, varscan2
- CD200 | c.13-29T>G | Intron (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- CSNK1D | c.886-577G>T | Intron (SNP) | VAF 9/170 reads (5%) | called by muse, mutect2
- DDIT4 | c.*569G>A | 3'UTR (SNP) | VAF 32/91 reads (35%) | catalogued as rs1234868996; called by muse, varscan2
- DIP2B | c.*1374G>A | 3'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- EP400 | c.2827+41A>C | Intron (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- ESRRG | c.*2471G>A | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- ESRRG | c.*391T>C | 3'UTR (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- F8 | c.*225T>A | 3'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- FPGT-TNNI3K | c.383-2718A>C | Intron (SNP) | VAF 65/147 reads (44%) | catalogued as COSV58566173; called by muse, mutect2, varscan2
- FST | c.*793T>C | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- GPRC5B | c.*1796G>A | 3'UTR (SNP) | VAF 21/82 reads (26%) | catalogued as rs543246512; called by muse, mutect2, varscan2
- H4C6 | c.*12G>A | 3'UTR (SNP) | VAF 74/265 reads (28%) | catalogued as rs774381956; called by muse, mutect2, varscan2
- HS3ST3B1 | c.*938G>T | 3'UTR (SNP) | VAF 27/141 reads (19%) | catalogued as rs913236736, COSV100714484; called by muse, mutect2, varscan2
- JADE2 | c.*3321T>C | 3'UTR (SNP) | VAF 45/145 reads (31%) | called by muse, mutect2, varscan2
- LINC02724 | n.2190C>A | RNA (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- LINC02876 | n.521G>A | RNA (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- LRRC2 | chr3:46516344 C>T | 3'Flank (SNP) | VAF 45/71 reads (63%) | catalogued as rs1329440815; called by muse, mutect2, varscan2
- MED17 | c.*1502C>T | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- MEX3B | c.*136G>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100313909; called by muse, mutect2
- MRM2 | c.-21_-11del | 5'UTR (DEL) | VAF 20/82 reads (24%) | called by pindel, varscan2
- MT1M | c.94+61G>A | Intron (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- MUC17 | c.12535+40G>A | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- MYO1C | c.*127C>T | 3'UTR (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100704454; called by muse, mutect2
- PEX5L | c.*4352G>T | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- PHACTR1 | c.104-40C>T | Intron (SNP) | VAF 15/66 reads (23%) | catalogued as rs1188188498; called by muse, mutect2, varscan2
- PIM2 | c.-171C>T | 5'UTR (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- POLE3 | c.*340T>A | 3'UTR (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- POLR2F | c.*32C>T | 3'UTR (SNP) | VAF 102/244 reads (42%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*3734T>G | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- PTPDC1 | c.83-493C>T | Intron (SNP) | VAF 11/164 reads (7%) | catalogued as rs762069819, COSV56624507; called by muse, mutect2
- RAB11FIP3 | c.*1130C>A | 3'UTR (SNP) | VAF 110/176 reads (63%) | called by muse, mutect2, varscan2
- RHOJ | c.*1911G>T | 3'UTR (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- RNF40 | c.*2156T>A | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- SAT2 | c.*21C>T | 3'UTR (SNP) | VAF 17/116 reads (15%) | catalogued as rs758016321; called by muse, mutect2, varscan2
- SEPTIN3 | c.1011+658C>A | Intron (SNP) | VAF 31/134 reads (23%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.*6256G>A | 3'UTR (SNP) | VAF 54/136 reads (40%) | called by muse, mutect2, varscan2
- SHOX2 | c.347-153G>A | Intron (SNP) | VAF 21/232 reads (9%) | catalogued as rs1013942054; called by muse, mutect2
- SLC16A7 | c.*652T>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- SLC16A7 | c.*2871C>T | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- SOX11 | c.*2087A>C | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- SREBF1 | c.*178C>G | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- SRR | c.*1367A>G | 3'UTR (SNP) | VAF 11/52 reads (21%) | catalogued as COSV56783917; called by mutect2, varscan2
- STT3B | c.*1210T>A | 3'UTR (SNP) | VAF 12/87 reads (14%) | catalogued as rs1000033641; called by muse, mutect2, varscan2
- SV2B | c.*4442G>A | 3'UTR (SNP) | VAF 55/242 reads (23%) | catalogued as rs543520263; called by muse, mutect2, varscan2
- SYNE1 | c.25788+10G>A | Intron (SNP) | VAF 39/194 reads (20%) | called by muse, mutect2, varscan2
- TFEC | c.663+146G>A | Intron (SNP) | VAF 38/111 reads (34%) | catalogued as rs540863191; called by muse, mutect2, varscan2
- TGFA | c.*3234C>T | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, varscan2
- TMBIM6 | c.-31+737G>T | Intron (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- TMEM241 | c.*779T>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- TNFSF13 | c.*243G>A | 3'UTR (SNP) | VAF 17/192 reads (9%) | called by muse, mutect2
- TNS1 | c.4331-19T>G | Intron (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- TREML2 | c.*1385C>T | 3'UTR (SNP) | VAF 51/148 reads (34%) | called by muse, mutect2, varscan2
- TSLP | chr5:111070288 G>A | 5'Flank (SNP) | VAF 187/305 reads (61%) | called by muse, mutect2, varscan2
- TTC3 | c.-805del | 5'UTR (DEL) | VAF 56/182 reads (31%) | catalogued as rs34615228; called by mutect2, varscan2
- WFDC9 | c.*152A>G | 3'UTR (SNP) | VAF 51/164 reads (31%) | called by muse, mutect2, varscan2
